Gene-level copy-number profile of tumor specimen TCGA-BI-A20A-01A from TCGA case TCGA-BI-A20A, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; AJCC pathologic stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 49.9 years (18,215 days).
Specimen TCGA-BI-A20A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e7e675d2-8e97-4d25-854e-53fd491cf569.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BI-A20A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b29e5e18-0c66-48c5-9571-b9373ce9142e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,218; copy number 2: 39,901; copy number 3: 1,476; copy number 4: 3,728; copy number 5: 297; copy number 6: 120; copy number 9: 19; copy number 13: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BI-A20A-01A-11D-A14V-01): tumor purity 0.46, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 212 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:73,052,362–74,011,876, 26 genes, copy number 6: COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P.
- chr4:74,917,822–79,696,837, 94 genes, copy number 6 (broad region; genes not listed).
- chr12:911,736–1,788,674, 14 genes, copy number 5: RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr12:1,800,862–1,807,486, 1 gene, copy number 5: AC005343.7.
- chr20:31,257,664–33,073,628, 77 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
